Surgical pathology report (de-identified scan), TCGA case TCGA-J9-A8CP, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Melbourne Health, specimen TCGA-J9-A8CP-01A (Primary Tumor).

[page 1 of 2]
CLCF *ICD-O-3*
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
JA 11/27/13

DOB:

Sex:

Episode Results

1. HIST

Doctor Details

Requesting Doctor:

Copy-To Doctors:

Episode Details

Status:

Results Available

Collection Date:

Reported Date:

Episode:

HISTOPATHOLOGY REPORT

CLINICAL NOTES :

PSA 6.6, DRE - Firm Right apex, Prostate volume 33 cc, TRUS prostate biopsy

MACROSCOPIC :

Specimen 1: Labelled Right apex. Core biopsies 2, 10, 15 mm.

Specimen 2: Labelled Left apex. Core biopsies 2, 2, 10, 16 mm A1

Specimen 3: Labelled Right mid. Core biopsies 13, 13 mm.

Specimen 4: Labelled Left mid. Core biopsies 16, 22 mm A1

Specimen 5: Labelled Right base. Core biopsies 14, 16 mm.

Specimen 6: Labelled Left base. Core biopsies 16, 18 mm A1 Right side blue

MICROSCOPIC :

Right apex:

Adenocarcinoma. Gleason pattern **4+4=8** , involving 11 mm of one core and a separate focus of adenocarcinoma. Gleason pattern **3+3=6** , involving 5 mm of another core.

Left apex:

The core biopsy is benign.

Right mid:

[page 2 of 2]
Adenocarcinoma, Gleason pattern 3+3=6 , involving 1 and 2 mm of two cores.

Left mid:

The core biopsy is benign.

Right and left base:

The core biopsies are benign.

CONCLUSION:

Multiple prostatic needle biopsies -- right-sided adenocarcinoma.

Reported by _____ Slides seen in conjunction with _____

All Rights Reserved.

Email:

IUPAA Discrepancy		

Source: NCI Genomic Data Commons file 2f561adc-aff0-45f7-9015-adf8fa13b095 (TCGA-J9-A8CP.526E96AC-D8A9-4FED-8D31-05E2427DE513.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).